Somatic mutation profile of tumor specimen TCGA-AX-A2HF-01A (aliquot TCGA-AX-A2HF-01A-11D-A17D-09) from TCGA case TCGA-AX-A2HF, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 67.6 years (24,689 days).
Specimen TCGA-AX-A2HF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) afe57028-1ca1-45c8-8f63-ab4f946f7a38.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A2HF-10A (Blood Derived Normal), aliquot TCGA-AX-A2HF-10A-01D-A17D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb12afcd-ee7f-4f85-8f97-109e9959ec2c

The open-access MAF lists 32 somatic variants for this specimen: 25 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 17, Silent 7, Nonsense Mutation 4, Frame Shift Del 2, Nonstop Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 21/33 reads (64%) | catalogued as rs775126020, CM980087, COSV57320525; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CLRN1 | c.619C>T p.R207* | Nonsense Mutation (SNP) | VAF 22/70 reads (31%) | catalogued as rs373208120, CM127995, COSV55804457; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3132T>G p.N1044K | Missense Mutation (SNP) | VAF 46/90 reads (51%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen possibly damaging (0.63); catalogued as COSV55875087, COSV55897116; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 37/54 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.1512del p.Q505Sfs*114 | Frame Shift Del (DEL) | VAF 203/318 reads (64%) | catalogued as COSV61370856; called by mutect2, pindel, varscan2
- COG7 | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.863); catalogued as COSV56149005; called by muse, mutect2, varscan2
- COL11A1 | c.2300C>A p.A767E | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.601); catalogued as rs372933541, COSV100616794, COSV62171819; called by muse, mutect2, varscan2
- CSF3R | c.2511G>C p.*837Yext*15 | Nonstop Mutation (SNP) | VAF 17/28 reads (61%) | catalogued as COSV58963049; called by muse, mutect2, varscan2
- FAM9A | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.437); catalogued as COSV66812888; called by muse, mutect2, varscan2
- GAB4 | c.781G>C p.D261H | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as COSV68752847; called by muse, mutect2, varscan2
- H4C7 | c.141C>G p.I47M | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV55099106, COSV55100492; called by muse, mutect2, varscan2
- HFE | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV58512365; called by muse, mutect2, varscan2
- METAP1D | c.154A>G p.I52V | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV59928748; called by muse, mutect2, varscan2
- MPPED2 | c.559G>T p.G187C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV63895856; called by muse, mutect2, varscan2
- OPCML | c.218C>A p.T73N | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.041); catalogued as COSV59401704, COSV59423681; called by muse, mutect2, varscan2
- OSBPL1A | c.1286G>C p.R429T | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.643); catalogued as COSV60194874; called by muse, mutect2, varscan2
- PKNOX1 | c.331G>C p.D111H | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52334086; called by muse, varscan2
- PLBD1 | c.798A>G p.I266M | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.262); catalogued as COSV53691573; called by muse, mutect2, varscan2
- SLC8A1 | c.2393G>A p.W798* | Nonsense Mutation (SNP) | VAF 50/84 reads (60%) | catalogued as COSV100244961, COSV60469972; called by muse, mutect2, varscan2
- STRN3 | c.1193C>T p.S398L | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as COSV62578261; called by muse, mutect2, varscan2
- AC242842.3 | c.1187G>T p.R396L | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0.093); called by muse, varscan2
- CBX1 | c.394_399del p.L132_M133del | In Frame Del (DEL) | VAF 22/32 reads (69%) | called by mutect2, pindel, varscan2
- CDK12 | c.4447G>A p.G1483R (on ENST00000447079 / NM_016507.4; = p.G1474R on NM_015083.3) | Missense Mutation (SNP) | VAF 18/19 reads (95%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRT36 | c.915_922del p.C305* | Nonsense Mutation (DEL) | VAF 23/53 reads (43%) | called by mutect2, pindel, varscan2
- PRRC2C | c.2017_2018del p.L673Tfs*36 (on ENST00000367742; = p.L671Tfs*36 on NM_015172.4) | Frame Shift Del (DEL) | VAF 21/47 reads (45%) | called by mutect2, pindel, varscan2
- CDH19 | c.408C>A p.I136= | Silent (SNP) | VAF 49/118 reads (42%) | catalogued as COSV50954177; called by muse, mutect2, varscan2
- KNL1 | c.2904T>C p.T968= (on ENST00000346991 / NM_170589.5; = p.T942= on NM_144508.5) | Silent (SNP) | VAF 18/24 reads (75%) | catalogued as COSV61150720; called by muse, mutect2, varscan2
- MEGF10 | c.1509C>T p.N503= | Silent (SNP) | VAF 13/21 reads (62%) | catalogued as rs142355199, COSV57244519; called by muse, mutect2, varscan2
- MYH14 | c.1746C>T p.F582= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV51809602; called by muse, mutect2, varscan2
- PAX9 | c.864C>T p.T288= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs978630496, COSV58714023; called by muse, mutect2, varscan2
- SEPTIN5 | c.861C>G p.L287= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV63530332; called by muse, mutect2, varscan2
- TLN2 | c.2517C>G p.L839= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV60885164, COSV60893331; called by muse, mutect2
